Somatic mutation profile of tumor specimen TCGA-RA-A741-01A (aliquot TCGA-RA-A741-01A-11D-A33O-09) from TCGA case TCGA-RA-A741, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 34.5 years (12,607 days).
Specimen TCGA-RA-A741-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5ae8464-296b-429f-bcbb-76890126ca9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RA-A741-10B (Blood Derived Normal), aliquot TCGA-RA-A741-10B-01D-A33O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad01c5f9-b216-4c8c-b67c-b24612039c30

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, Frame Shift Del 3, Nonsense Mutation 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP2 | c.1238G>T p.S413I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV62140552; called by muse, mutect2, varscan2
- MAGEC2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as rs142943547, COSV55997506, COSV55999092; called by muse, mutect2, varscan2
- MUC16 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.895); catalogued as COSV67441301; called by muse, mutect2, varscan2
- MUC4 | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV62125595, COSV62190452; called by muse, mutect2, varscan2
- MUC4 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV62125602; called by muse, mutect2, varscan2
- MUC4 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.374); catalogued as COSV62125608; called by muse, mutect2, varscan2
- MUC4 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.374); catalogued as rs1054616127, COSV62125615; called by muse, mutect2, varscan2
- OR2AG1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100264835; called by muse, mutect2
- OSBPL8 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53877576; called by muse, mutect2, varscan2
- PROM1 | c.1752T>A p.H584Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV71699071; called by muse, varscan2
- ROBO2 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs777291992, COSV59893855; called by muse, mutect2, varscan2
- RYR2 | c.7981C>T p.L2661F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63657537; called by muse, mutect2, varscan2
- TBC1D25 | c.1934T>G p.M645R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65123143; called by muse, mutect2, varscan2
- TOR1AIP2 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100857344; called by muse, mutect2
- TRO | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV51497052; called by muse, mutect2, varscan2
- UBAP2L | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV55167007; called by muse, mutect2, varscan2
- UBAP2L | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV55168476, COSV55173895, COSV55177354, COSV99670916; called by muse, mutect2
- UVRAG | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV62100878; called by muse, mutect2, varscan2
- ZNF169 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.408); catalogued as rs752335559, COSV61762975; called by mutect2, varscan2
- ZNF831 | c.153del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs750329558; called by mutect2, varscan2
- CHAMP1 | c.2139_2158del p.C714Kfs*10 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, pindel
- IGKV1D-43 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZDHHC15 | c.77_87del p.L26Pfs*13 | Frame Shift Del (DEL) | VAF 11/112 reads (10%) | called by mutect2, pindel
- EPN2 | c.39C>T p.I13= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs150823408; called by muse, mutect2, varscan2
- FRMPD4 | c.534A>G p.V178= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV101042543; called by muse, mutect2
- UGT8 | c.621C>A p.V207= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV60416172; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506182 G>A | 3'Flank (SNP) | VAF 54/110 reads (49%) | called by muse, mutect2, varscan2
- TTN | c.34265-5067C>G | Intron (SNP) | VAF 7/68 reads (10%) | catalogued as rs1187195115, COSV59864070; called by muse, mutect2, varscan2
